Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7996, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7996-01A (Primary Tumor).

[page 1 of 4]
Referring Physician:

DOB: Age: Gender: F

Ref#: Hosp#: Provider Group :

Date of Service: Date Received:

Room: Bed:

Case #:

Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. & B.) PORTION OF KIDNEY, RESECTION:

- RENAL CELL CARCINOMA, PAPILLARY VARIANT, TYPE I.
- Tumor measures 3.0 cm in greatest dimension.
- MARGINS: NEGATIVE.
- LYMPH NODES: NONE IDENTIFIED.
- SEE COMMENTS.

PATHOLOGIC TUMOR STAGING DESCRIPTORS:

Histologic type and grade: Renal cell carcinoma, papillary variant, type I.

Primary tumor: pT1a.

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Margin status: R0.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

COMMENT: Immunohistochemical staining is positive for OSCAR-CK, CK7, racemase, and CD10. It is negative for CK20 and CD117. This supports the given diagnosis.

COMMENT: Tumor extends to the parenchymal edge of specimen A. From pathologic examination alone, it is not possible to determine with certainty whether or not the portions of the parenchymal edge of specimen A which are involved by tumor are true margins or only "specimen margins" in which specimen B is the true surgical margin. Specimen B is negative for malignancy. Additionally, a substantial portion of tumor is less than 0.1cm from the parenchymal edge of specimen A; this area appears significantly larger than the aggregate size of all the tissue in specimen B. The margin status in this report was given following telephone conversation with [REDACTED] who stated that the pertinent specimen for establishing the margin in question (parenchymal margin) is specimen B.

Kidney Tumor Staging Information

Case #: [REDACTED]

Printed: [REDACTED]

Page 1

This report continues... (FINAL)

MR No. [REDACTED]

Acct No. [REDACTED]

Patient Name [REDACTED]

[page 2 of 4]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol.

Procedure:	Partial nephrectomy.
Specimen type:	Portion of kidney.
Specimen laterality:	Left.
TUMOR FEATURES:	
Tumor size:	3.0 x 3.0 x 2.2 cm.
Tumor focality:	Unifocal.
Histologic type:	Renal cell carcinoma, papillary variant, type I.
Sarcomatoid features:	Not identified.
Macroscopic extent of tumor:	Confined to kidney.
Microscopic tumor extension:	Confined to kidney.
LYMPH NODES:	None identified.
MARGIN EVALUATION:	
Distance to closest margin:	Negative.
Other margins:	<0.1cm.
	Negative.
PATHOLOGIC TUMOR STAGING DESCRIPTORS:	
Primary tumor:	pT1a.
Regional lymph nodes:	pNX.
Distant metastasis:	pMX.
Margin status:	R0.
Pathologic stage:	I.

Case #:
Printed:

Page 2
This report continues... (FINAL)

[page 3 of 4]
Case #:

Pathologic findings in non-neoplastic kidney:

None.

Additional pathologic findings:

None.

Comment:

N/A.

Source of Specimen:

- A. Left renal mass
- B. Left renal mass margins

Clinical History/Operative Dx:

Renal mass

Gross Description:

A. The specimen is labeled left renal mass and is received without fixative. It consists of a nearly spherical cortical portion of renal tissue measuring 3.2 x 3.1 x 2.8 cm and weighing 16 grams. There is a separate 5.5 x 3 x 0.7 cm portion of lobulated fatty tissue. The renal cortical tissue is inked at the apparent base of

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 4]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

excision. It is serially sectioned to reveal a soft easily disrupted pale yellow to pale red neoplasm which measures 3 x 3 x 2.2 cm. The non-cortical portion of the tumor appears to have a thin delicate capsule which is smooth. The neoplastic tissue centrally and paracentrally focally extends to the inked cortical margin. Representative sections of the neoplasm are obtained for research purposes. Representative sections of the neoplasm, to include the entire inked cortical margin, are submitted in cassettes A1-A7. The two furthest edges of the specimen are submitted in cassette A8. Representative sections of the separate fatty tissue are submitted in cassette A9.

B. The specimen is labeled left renal mass margin and is received without fixative. It consists of three irregular fragments of tan to hyperemic tissue which vary from an elongated strip measuring 0.9 x 0.2 x 0.1 cm to a roughly rectangular 0.6 x 0.3 x 0.3 cm fragment to a 0.3 cm small fragment. The tissue is submitted intact in cassette B1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #:

Printed:

Page 4

END OF REPORT (FINAL)

MR No. -

Acct No. -

Patient Name -

Source: NCI Genomic Data Commons file 34611969-118d-4d77-883a-f5e20c3e3f64 (TCGA-A4-7996.DABF8924-77E9-43CE-BCC8-7BDF47E6AF5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).